Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5522, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5522-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 5.6, sigmoid resection for [REDACTED]. The patient also has a history of biopsy on [REDACTED]. This biopsy reveals bilateral prostatic adenocarcinoma: right apex = Gleason grade 3+3 = 6; right mid = Gleason grade 3+4 = 7; right base = Gleason grade 3+3 = 6; left base = Gleason grade 3+4 = 7; left mid = Gleason grade 3+4 = 7; left apex = Gleason grade 3+3 = 6.
PRE-OP DIAGNOSIS: Prostate cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Radical retropubic prostatectomy.

FINAL DIAGNOSIS:

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN FOUR (4) LYMPH NODES EXAMINED.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN EIGHTEEN (18) LYMPH NODES EXAMINED.

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 3+4=7
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.9 cm.
- C. THE CARCINOMA INVOLVES 20% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: PT2c N0 Mx.
- K. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC PROSTATITIS ARE NOTED.

PART 4:

LEFT NEUROVASCULAR BUNDLE AT BASE:
BENIGN FIBROMUSCULAR TISSUE WITH NEUROVASCULAR BUNDLES.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
WEIGHT OF PROSTATE:	40.48gm
TUMOR SIZE:	Maximum dimension: 1.9 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	22
LYMPH NODES POSITIVE:	0
EXTRANODAL EXTENSION:	No
SIZE OF NODAL METASTASIS:	0mm
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

TCGA-EJ-5522

Source: NCI Genomic Data Commons file 24acf863-d754-4430-a9de-034d0bcb89ac (TCGA-EJ-5522.756659D2-5E97-40D4-AA4E-C6D777153D0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).